Somatic mutation profile of tumor specimen ALCH-B4VE-TTP1-A (aliquot ALCH-B4VE-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4VE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.5 years (26,483 days).
Specimen ALCH-B4VE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2001548-fd23-4cb4-923c-216ecfbdef03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4VE-NB1-A (Blood Derived Normal), aliquot ALCH-B4VE-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f4fd312-9a0d-43fd-bd99-e9cc41810681

The open-access MAF lists 21 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, RNA 2, Intron 2, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLCE | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 20/508 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV99961990; called by muse, mutect2
- PCCA | c.526G>T p.D176Y | Missense Mutation (SNP) | VAF 38/578 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100887083; called by muse, mutect2
- PLCB2 | c.3077C>T p.A1026V | Missense Mutation (SNP) | VAF 32/488 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs1258625010, COSV53030518; called by muse, mutect2
- RPA1 | c.1687C>T p.Q563* | Nonsense Mutation (SNP) | VAF 10/254 reads (4%) | catalogued as COSV54610787; called by muse, mutect2
- UBN1 | c.209A>G p.N70S | Missense Mutation (SNP) | VAF 28/328 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.037); catalogued as rs1321224992; called by muse, mutect2
- BICC1 | c.940A>G p.T314A | Missense Mutation (SNP) | VAF 48/820 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CCDC159 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 32/440 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- CEP152 | c.2593C>G p.R865G | Missense Mutation (SNP) | VAF 43/1114 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- DOCK1 | c.4820A>G p.K1607R | Missense Mutation (SNP) | VAF 15/363 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.577); called by muse, mutect2
- KRT5 | c.1417C>G p.L473V | Missense Mutation (SNP) | VAF 42/640 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SPIRE2 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- ZCCHC18 | c.128G>T p.R43I | Missense Mutation (SNP) | VAF 24/602 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2
- ZNF30 | c.1238C>T p.S413L | Missense Mutation (SNP) | VAF 26/460 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.19); called by muse, mutect2
- SLC40A1 | c.1396A>C p.R466= | Silent (SNP) | VAF 14/276 reads (5%) | called by muse, mutect2
- TMEM128 | c.273C>G p.V91= (on ENST00000382753 / NM_001297552.2; = p.V67= on NM_032927.3) | Silent (SNP) | VAF 26/310 reads (8%) | called by muse, mutect2
- TMEM266 | c.465A>C p.L155= | Silent (SNP) | VAF 20/293 reads (7%) | called by muse, mutect2
- CYP21A2 | c.293-33T>G | Intron (SNP) | VAF 15/451 reads (3%) | called by muse, mutect2
- DST | c.4297-3982T>C | Intron (SNP) | VAF 24/751 reads (3%) | called by muse, mutect2
- GLIS3 | c.-29T>G | 5'UTR (SNP) | VAF 67/746 reads (9%) | called by muse, mutect2
- SLC25A48-AS1 | n.27C>T | RNA (SNP) | VAF 28/414 reads (7%) | called by muse, mutect2
- ZNF252P | n.1706G>C | RNA (SNP) | VAF 10/156 reads (6%) | called by muse, mutect2
